Somatic mutation profile of tumor specimen TCGA-24-1565-01A (aliquot TCGA-24-1565-01A-01W-0551-08) from TCGA case TCGA-24-1565, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.1 years (27,048 days).
Specimen TCGA-24-1565-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 996cf857-ff74-4d32-aa94-96bec656b857.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1565-10A (Blood Derived Normal), aliquot TCGA-24-1565-10A-01W-0551-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f345879-668b-4d8d-82e0-6835fdbdbdc5

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 12, Splice Site 4, Nonsense Mutation 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANPEP | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV55589239; called by muse, mutect2, varscan2
- BEX1 | c.349C>G p.H117D | Missense Mutation (SNP) | VAF 414/1072 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV65579677; called by muse, mutect2, varscan2
- CD1C | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 121/428 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1258415181, COSV63807379; called by muse, mutect2, varscan2
- COL15A1 | c.1024G>A p.G342S | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.898); catalogued as rs137949756, COSV100898030; called by muse, mutect2, varscan2
- CTR9 | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1260788254, COSV63727812; called by muse, mutect2, varscan2
- EPB41L4B | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 158/386 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs768403763, COSV65801850; called by muse, mutect2, varscan2
- FBXW7 | c.1952T>A p.L651* (on ENST00000281708 / NM_001349798.2; = p.L571* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 141/444 reads (32%) | catalogued as COSV55894441; called by muse, mutect2, varscan2
- ISL1 | c.760A>G p.K254E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV57932198; called by muse, mutect2, varscan2
- JCAD | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 101/320 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as rs530709153, COSV64757702; called by muse, mutect2, varscan2
- KCND1 | c.1858G>A p.G620S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs782001324, COSV54412751; called by muse, mutect2, varscan2
- KRT12 | c.68C>G p.S23W | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV52429778; called by muse, mutect2, varscan2
- LANCL2 | c.678+1G>A p.X226_splice | Splice Site (SNP) | VAF 118/318 reads (37%) | catalogued as COSV54647609; called by muse, mutect2, varscan2
- MYH4 | c.4656+2T>A p.X1552_splice | Splice Site (SNP) | VAF 24/51 reads (47%) | catalogued as COSV55112423; called by muse, mutect2, varscan2
- NEK10 | c.1750C>T p.H584Y | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100411520; called by muse, mutect2, varscan2
- OR3A2 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 78/197 reads (40%) | catalogued as rs373734930; called by muse, mutect2, varscan2
- PCDHA9 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV65323542, COSV65327324; called by muse, mutect2
- PCDHGB7 | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV99543782; called by muse, mutect2
- PEAR1 | c.206+1G>A p.X69_splice | Splice Site (SNP) | VAF 127/194 reads (65%) | catalogued as rs373109940, COSV52770824; called by muse, mutect2, varscan2
- PITX1 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV54761544; called by muse, mutect2, varscan2
- PLCB1 | c.3148C>A p.Q1050K | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV62038752; called by muse, mutect2, varscan2
- ROBO3 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.041); catalogued as COSV101185141; called by muse, mutect2, varscan2
- ROBO3 | c.2612A>G p.E871G | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV101185143; called by muse, mutect2, varscan2
- SIGLEC1 | c.3232G>A p.A1078T | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.559); catalogued as COSV52458754; called by muse, mutect2, varscan2
- SLC17A7 | c.1654A>G p.R552G | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV99677016; called by muse, mutect2
- SLC24A2 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53857731; called by muse, mutect2, varscan2
- STK4 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.354); catalogued as rs746946767, COSV65669423; called by muse, mutect2, varscan2
- TENM3 | c.6257G>A p.R2086H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753345698, COSV69299585; called by muse, mutect2, varscan2
- GRIA2 | c.1624_1630del p.L542Mfs*16 | Frame Shift Del (DEL) | VAF 326/988 reads (33%) | called by mutect2, pindel, varscan2
- PIK3R2 | c.1291-17_1295del p.X431_splice | Splice Site (DEL) | VAF 32/146 reads (22%) | called by mutect2, pindel, varscan2
- PRKDC | c.6663del p.K2221Nfs*18 | Frame Shift Del (DEL) | VAF 52/100 reads (52%) | called by mutect2, pindel, varscan2
- CCDC85A | c.837G>C p.P279= | Silent (SNP) | VAF 44/180 reads (24%) | catalogued as COSV101339474, COSV101339518; called by muse, mutect2, varscan2
- CD207 | c.30G>A p.A10= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as rs575060537, COSV69651655; called by muse, mutect2, varscan2
- CHML | c.807G>T p.R269= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV59362556; called by muse, mutect2, varscan2
- GRIA1 | c.2553C>T p.N851= | Silent (SNP) | VAF 55/178 reads (31%) | catalogued as rs771436134, COSV53589376; called by muse, mutect2, varscan2
- GRIA4 | c.858G>A p.E286= | Silent (SNP) | VAF 104/305 reads (34%) | catalogued as rs1470792934, COSV56882539; called by muse, mutect2, varscan2
- NLRP3 | c.1872C>T p.S624= | Silent (SNP) | VAF 427/685 reads (62%) | catalogued as COSV100276463, COSV60225963; called by muse, mutect2, varscan2
- NOCT | c.343A>C p.R115= | Silent (SNP) | VAF 47/147 reads (32%) | catalogued as COSV54935451; called by muse, mutect2, varscan2
- NRP2 | c.1020G>A p.T340= | Silent (SNP) | VAF 57/146 reads (39%) | catalogued as rs764138566, COSV55923454; called by muse, mutect2, varscan2
- OPHN1 | c.390G>A p.R130= | Silent (SNP) | VAF 66/159 reads (42%) | catalogued as COSV100830683; called by muse, mutect2, varscan2
- PTPRG | c.2109C>T p.R703= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as rs371158794, COSV55629038; called by muse, mutect2, varscan2
- SEMA4D | c.387C>T p.N129= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as rs758493080, COSV59391906; called by muse, mutect2, varscan2
- TICAM1 | c.678G>A p.G226= | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as COSV50229470; called by muse, mutect2, varscan2
- SNX29P2 | n.1085C>T | RNA (SNP) | VAF 17/84 reads (20%) | catalogued as rs765243721; called by muse, mutect2, varscan2
